Somatic mutation profile of tumor specimen TCGA-DJ-A1QG-01A (aliquot TCGA-DJ-A1QG-01A-11D-A14W-08) from TCGA case TCGA-DJ-A1QG, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary carcinoma, follicular variant; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 62.6 years (22,859 days).
Specimen TCGA-DJ-A1QG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 57cfa1d4-f8c1-45ea-b75e-c9056dd1ab54.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DJ-A1QG-10A (Blood Derived Normal), aliquot TCGA-DJ-A1QG-10A-01D-A14W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5f0d8031-5e94-4369-80b7-9630a890481b

The open-access MAF lists 15 somatic variants for this specimen: 12 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 11, Silent 3, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 56/169 reads (33%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ARMT1 | c.250G>C p.D84H | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1279326377, COSV66179079; called by muse, mutect2, varscan2
- C16orf91 | c.301G>A p.A101T | Missense Mutation (SNP) | VAF 46/125 reads (37%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as COSV59950953; called by muse, mutect2, varscan2
- C1orf112 | c.1792C>T p.Q598* | Nonsense Mutation (SNP) | VAF 27/89 reads (30%) | catalogued as COSV53682618; called by muse, mutect2, varscan2
- CDH11 | c.1063G>T p.D355Y | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV51774410, COSV51776848, COSV99219561; called by muse, mutect2, varscan2
- CHEK2 | c.1302G>T p.L434F (on ENST00000382580 / NM_001005735.2; = p.L391F on NM_007194.4) | Missense Mutation (SNP) | VAF 28/44 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV60426007; called by muse, mutect2, varscan2
- DMP1 | c.1514A>T p.D505V | Missense Mutation (SNP) | VAF 60/154 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56822121; called by muse, mutect2, varscan2
- H4C11 | c.10C>G p.R4G | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.139); catalogued as COSV61827472; called by mutect2, varscan2
- INHBC | c.733A>G p.R245G | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.131); catalogued as COSV59006170; called by muse, mutect2, varscan2
- ITGA10 | c.1838G>A p.R613Q | Missense Mutation (SNP) | VAF 35/115 reads (30%) | SIFT tolerated (0.36); PolyPhen benign (0.027); catalogued as rs781987259, COSV65195979; called by muse, mutect2, varscan2
- NOMO1 | c.1507G>T p.A503S | Missense Mutation (SNP) | VAF 71/238 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.835); catalogued as COSV55061283; called by muse, mutect2, varscan2
- THBS2 | c.1378C>T p.R460C | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100827649, COSV64682108; called by muse, mutect2, varscan2
- ICAM3 | c.126G>A p.V42= | Silent (SNP) | VAF 23/63 reads (37%) | catalogued as COSV50330074; called by muse, mutect2, varscan2
- MS4A12 | c.672C>G p.A224= | Silent (SNP) | VAF 15/57 reads (26%) | catalogued as COSV50015627; called by muse, mutect2, varscan2
- OR6F1 | c.142T>C p.L48= | Silent (SNP) | VAF 9/132 reads (7%) | catalogued as rs1243770579, COSV57469393; called by muse, mutect2
